Gene-level copy-number profile of tumor specimen TCGA-98-8023-01A from TCGA case TCGA-98-8023, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 70.5 years (25,732 days).
Specimen TCGA-98-8023-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.a7f4515d-7d84-4afd-abd3-9afa03021ac8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-98-8023-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6c713e15-c4b2-46f4-b9be-c4f5c7328844

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 105; copy number 1: 31,892; copy number 2: 22,741; copy number 3: 2,823; copy number 4: 1,655; copy number 5: 413; copy number 6: 17; copy number 7: 16; copy number 8: 88; copy number 10: 8; copy number 11: 16; copy number 12: 6; copy number 13: 1; copy number 17: 2; copy number 24: 37.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-98-8023-01A-11D-2243-01): tumor purity 0.29, ploidy 2.74, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 105 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,278,050–22,128,103, 36 genes: IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.
- chr14:106,460,092–106,875,071, 69 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 5,082 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–153,348,841, 418 genes, copy number 5–10 (broad region; genes not listed).
- chr2:950,849–17,386,417, 235 genes, copy number 3–24 (within-gene range 1–24) (broad region; genes not listed).
- chr2:18,403,967–64,593,005, 783 genes, copy number 3 (broad region; genes not listed).
- chr3:149,318,498–177,959,817, 418 genes, copy number 4 (broad region; genes not listed).
- chr3:187,668,912–192,917,856, 57 genes, copy number 3: SST, RTP2, AC072022.1, BCL6, AC072022.2, AC108681.1, AC068295.1, LINC01991, AC092941.1, AC092941.2, AC022498.1, LPP-AS2, LPP, FLJ42393, LPP-AS1, MIR28, TPRG1-AS1, TPRG1, AC009319.1, TPRG1-AS2, TP63, AC078809.1, MIR944, P3H2, MTAPP2, P3H2-AS1, RNU6-1109P, NMNAT1P3, CLDN1, CLDN16, TMEM207, IL1RAP, GCNT1P3, RN7SKP296, AC108747.1, LINC02013, CCT6P4, AC092952.1, GMNC, OSTN, OSTN-AS1, UTS2B, CCDC50, AC073365.1, PYDC2, Y_RNA, AC026320.2, AC026320.1, AC026320.3, RN7SKP222, FGF12, FGF12-AS1, FGF12-AS2, FGF12-AS3, AC026671.1, RNU1-20P, MB21D2.
- chr4:173,094,868–190,092,279, 262 genes, copy number 3 (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 4 (broad region; genes not listed).
- chr6:49,499,923–57,222,307, 131 genes, copy number 3 (broad region; genes not listed).
- chr6:57,390,132–57,390,212, 1 gene, copy number 3: MIR548U.
- chr6:162,568,379–170,738,536, 157 genes, copy number 3 (broad region; genes not listed).
- chr7:33,109,557–33,877,180, 1 gene, copy number 3 (within-gene range 2–3): BBS9.
- chr7:33,725,981–63,088,261, 491 genes, copy number 3 (broad region; genes not listed).
- chr8:122,671,291–122,781,071, 5 genes, copy number 6: AC100872.1, AC100872.2, CDK5P1, AC016405.3, AC016405.2.
- chr10:16,276,871–45,672,780, 495 genes, copy number 4 (within-gene range 2–4) (broad region; genes not listed).
- chr12:752,579–7,189,069, 204 genes, copy number 3–11 (within-gene range 2–11) (broad region; genes not listed).
- chr12:25,385,670–25,409,445, 3 genes, copy number 7: AC087239.1, RNU4-67P, AC092451.1.
- chr12:25,423,600–25,441,052, 3 genes, copy number 7: AC092451.2, FAM133GP, TUBB4BP1.
- chr12:30,709,552–34,249,958, 95 genes, copy number 3–4 (within-gene range 2–4) (broad region; genes not listed).
- chr12:126,165,730–133,214,832, 213 genes, copy number 3 (broad region; genes not listed).
- chr17:34,319,435–35,864,615, 68 genes, copy number 3 (within-gene range 1–3) (broad region; genes not listed).
- chr17:69,577,251–80,966,371, 332 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 29,823. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
